Somatic mutation profile of tumor specimen 0DX7FL from CCDI case PBCPLP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (983 days).
Specimen 0DX7FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 718adf44-4a2a-4379-aefb-6046b0948a89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ce07975-ff16-40a3-9c8c-ec3f0637c054

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRDN | c.801T>G p.Y267* | Nonsense Mutation (SNP) | VAF 20/737 reads (3%) | called by muse, mutect2
- CCDC60 | c.564G>T p.P188= | Silent (SNP) | VAF 115/572 reads (20%) | called by muse, mutect2, varscan2
- AQP8 | c.-23G>A | 5'UTR (SNP) | VAF 109/495 reads (22%) | catalogued as rs372794800; called by muse, mutect2, varscan2
